Somatic mutation profile of tumor specimen TARGET-10-PAUCDY-09A (aliquot TARGET-10-PAUCDY-09A-01D) from TARGET case TARGET-10-PAUCDY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,632 days).
Specimen TARGET-10-PAUCDY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9ef126f-7af5-4225-bec9-5d142fd3e9c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUCDY-10A (Blood Derived Normal), aliquot TARGET-10-PAUCDY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e601a20-fd28-43fc-b084-01279bcf46be

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLIP1 | c.4127G>T p.R1376L (on ENST00000620786 / NM_001247997.1; = p.R1365L on NM_002956.2) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56810847; called by muse, varscan2
- ENPP2 | c.1933G>A p.V645I (on ENST00000075322 / NM_001040092.3; = p.V697I on NM_006209.5) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs879040983, COSV50010024, COSV50030870; called by muse, mutect2, varscan2
- FLT3 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- FRAS1 | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs773906563, COSV53638625; called by muse, mutect2, varscan2
- GSE1 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs375499456; called by muse, mutect2, varscan2
- LRRIQ1 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs142901418, COSV101280691; called by muse, varscan2
- UTP20 | c.2735C>A p.A912E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV55383724; called by muse, mutect2, varscan2
- ZNF169 | c.1772C>A p.T591N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV61766049; called by muse, mutect2, varscan2
- HIVEP1 | c.4735C>A p.H1579N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.038); called by muse, mutect2
- KDM1B | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.561); called by muse, varscan2
- LRRC36 | c.2041C>A p.Q681K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SINHCAF | c.229-1G>T p.X77_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- TSSK2 | c.1041C>A p.H347Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2
- GREB1 | c.5001C>A p.S1667= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- HEXD | c.846G>A p.A282= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs773429268, COSV100027757, COSV60064269; called by muse, mutect2, varscan2
- ZNF469 | c.6180C>A p.S2060= (on ENST00000437464; = p.S2088= on NM_001367624.2) | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- AKT2 | c.639+217G>T | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- ANO3 | c.591+13C>A | Intron (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ATP2A3 | c.1096-17G>T | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs571797898; called by mutect2, varscan2
